Gene-level copy-number profile of tumor specimen TCGA-32-1978-01A from TCGA case TCGA-32-1978, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 57.6 years (21,054 days).
Specimen TCGA-32-1978-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.0a93db71-8d5f-4490-8c50-775502ab55ee.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 5,101 have no estimate.
https://portal.gdc.cancer.gov/files/b0347788-9132-4fb0-9a54-2e4ee299f44d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 205; copy number 1: 5,404; copy number 2: 45,492; copy number 3: 4,421.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-32-1978-01): tumor purity 0.99, ploidy 1.99, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 205 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:8,026,738–8,344,167, 8 genes (within-gene range 0–1): AL034417.2, AL358876.1, LINC01714, RNU1-7P, AL358876.2, RNU6-991P, SLC45A1, Y_RNA.
- chr1:8,424,645–8,435,013, 1 gene: RERE-AS1.
- chr6:160,531,482–162,727,775, 18 genes: LPA, AL109933.2, AL109933.1, PLG, AL109933.5, AL109933.4, AL109933.3, AL391361.2, AL391361.1, AL139393.2, AL139393.1, MAP3K4-AS1, MAP3K4, AGPAT4, PRKN, AL132982.1, AL138716.1, KRT8P44.
- chr7:54,721,724–55,260,256, 9 genes: AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2.
- chr9:20,999,509–22,455,740, 56 genes: HACD4, IFNNP1, IFNB1, IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1.
- chr12:66,251,082–71,927,248, 113 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 5,404. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
